Surgical pathology report (de-identified scan), TCGA case TCGA-28-5219, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-5219-01A (Primary Tumor).

[page 1 of 4]
Patient: [REDACTED]

Accession Number: [REDACTED]

Hospital No: [REDACTED]

Pathologist: [REDACTED]

Ordering M.D.: [REDACTED]

Date of Birth: [REDACTED]

Assistant: [REDACTED]

Age/Sex: [REDACTED]

Date of Procedure: [REDACTED]

Copies To: [REDACTED]

Date Received: [REDACTED]

Location: [REDACTED]

TCGA-28-5219

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

DIAGNOSIS:

A. RIGHT TEMPORAL TUMOR FS #1 (CRANIOTOMY FOR RESECTION):

- Glioblastoma multiforme, WHO grade IV ✓

B. RIGHT TEMPORAL, NCI PROTOCOL #1:

- Cellular tumor without tumor necrosis in both pieces

C. RIGHT TEMPORAL, NCI PROTOCOL #2:

- Cellular tumor without tumor necrosis in one piece
- One piece of mildly hypercellular white matter

D. RIGHT TEMPORAL, NCI PROTOCOL #3:

- Cellular tumor without tumor necrosis in one piece
- One piece of unremarkable gray matter

E. RIGHT TEMPORAL, NCI PROTOCOL #4:

- Cellular tumor without tumor necrosis in both pieces

F. RIGHT TEMPORAL, NCI PROTOCOL #5:

- Cellular tumor without tumor necrosis in one piece
- One piece of moderately cellular tumor without tumor necrosis

G. RIGHT TEMPORAL (CRANIOTOMY FOR RESECTION):

- Glioblastoma multiforme, WHO grade IV

H. RIGHT TEMPORAL, CLINICAL TRIAL (CRANIOTOMY):

- Glioblastoma multiforme, WHO grade IV

I. BRAIN TUMOR (CRANIOTOMY FOR RESECTION):

- Glioblastoma multiforme, WHO grade IV

J. ARTIFICIAL DURA, RESECTION:

- Dense fibrous tissue with attached brain tissue showing hemorrhage and reactive change

K. HARDWARE EXPLANT:

- Explanted hardware (gross only)

COMMENT: Immunostain for MGMT is considered to be negative (less than 2% tumor cells positive). Tumor cells are essentially negative for P53, with some tumor cells negative for PTEN (partial PTEN loss) and MAPK. There is high MIB-1 labeling index

Patient Case(s): [REDACTED]

Copy For: [REDACTED]

Page 1 of 5

PATIENT NOTIFIED OF RESULTS		
DR:	NURSE:	DATE:

[page 2 of 4]
PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

(about 70% tumor cells positive). Lamina beta-1 is markedly elevated and lamina beta-2 is decreased (See Note).

EGFR amplification study has been ordered and results will be issued in an addendum.

Note:

A low percentage of tumor cells (20% and less) immunostaining for MGMT has been reported to be associated with a relative response to [REDACTED]. Hence, the 10% result in this case may suggest a likelihood of being responsive to [REDACTED].

Retained expression of PTEN was found to be associated with a more favorable prognosis in patients with high grade gliomas [REDACTED]. Hence, loss of PTEN expression in this case may suggest the possibility of a relatively unfavorable prognosis.

Presence of activated (phosphorylated) p42/44 mitogen-activated protein kinase (pMAPK) in glioblastoma multiforme has been shown to be associated with a relative resistance to radiation therapy [REDACTED]. Hence, a low percentage of tumor cells immunoreactive to pMAPK antibody (although a cut-off point has not been well established yet at the moment) in this case may suggest the possibility of a relative response to radiation therapy.

Recent studies have shown an adverse prognostic significance of increased laminin β 1 (laminin-8) and decreased laminin β 2 (laminin-9) expression predicting a worse survival of patients with high grade gliomas [REDACTED]. Association between laminin-8 and glial tumor grade, recurrence, and patient survival. [REDACTED]. Hence, elevated expression of laminin β 1 and decreased expression of β 2 in this tumor may suggest a least favorable prognosis.

However, the use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents.

HISTORY:

Glioblastoma status post previous biopsy/subtotal resection on [REDACTED]

MICROSCOPIC FINDINGS:

See diagnosis.

SPECIAL STUDIES:

EGFR amplification (I2)

IMMUNOHISTOCHEMISTRY:

MGMT, PTEN, P53, MIB-1, MAPK, Laminin beta 1 and laminin beta 2 (block I2)

GROSS:

A. RIGHT TEMPORAL TUMOR FS #1

Labeled with the patient's name, not otherwise designated, and received fresh for frozen section evaluation and subsequently fixed in formalin is a 0.4 x 0.3 x 0.2 cm soft tan tissue fragment. Entirely submitted.

A1. Frozen section control for FSA1 - 1

B. RIGHT TEMPORAL NCI #1

Labeled with the patient's name, "right temporal NCI", received fresh and subsequently fixed in formalin is a 0.9 x 0.7 x 0.2 cm soft tan tissue fragment. Entirely submitted.

B1. 1

C. RIGHT TEMPORAL NCI #2

Labeled with the patient's name, labeled "right temporal NCI", received fresh and subsequently fixed in formalin is a 0.9 x 0.3 x 0.2 cm soft tan tissue fragment. Entirely submitted.

C1. 1

D. RIGHT TEMPORAL NCI #3

[page 3 of 4]
PATIENT: [REDACTED]

***** Tumor - Please See End of Report *****
ACCESSION #: [REDACTED]

Labeled with the patient's name, labeled "right temporal NCI", received fresh and subsequently fixed in formalin is a 0.7 x 0.3 x 0.2 cm soft tan tissue fragment. Entirely submitted.

D1. 1

E. RIGHT TEMPORAL NCI #4

Labeled with the patient's name, labeled "right temporal NCI", received fresh and subsequently fixed in formalin is a 0.7 x 0.6 x 0.3 cm soft tan tissue fragment. Entirely submitted.

E1. 1

F. RIGHT TEMPORAL NCI #5

Labeled with the patient's name, labeled "right temporal NCI", received fresh and subsequently fixed in formalin is a 1.6 x 0.6 x 0.2 cm soft tan tissue fragment. Entirely submitted.

F1. 1

G. RIGHT TEMPORAL

Labeled with the patient's name, labeled "right temporal", and received in formalin is a 1.1 x 1.0 x 0.9 cm aggregate of soft tan friable tissue fragments. Entirely submitted.

G1. Largest portion of tissue, trisected - 3

G2. Smaller fragments - multiple

H. RIGHT TEMPORAL CLINICAL TRIAL

Labeled with the patient's name, labeled "right temporal clinical trial", and received in formalin are two tan soft tissue fragments measuring 0.7 x 0.7 x 0.3 and 0.9 x 0.4 x 0.3 cm. Entirely submitted.

H1. 2

I. BRAIN TUMOR

Labeled with the patient's name, labeled "brain tumor", and received in formalin are two friable tan tissue fragments measuring 1.7 x 0.7 x 0.5 and 2.7 x 0.8 x 0.3 cm. Entirely submitted.

I1. Larger portion of tissue - 1

I2. Smaller portion of tissue - 1

J. ARTIFICIAL DURA

Labeled with the patient's name, labeled "artificial dura", and received in formalin is a 3.7 x 2.2 x 0.3 cm portion of thin membranous tissue with one shiny surface. No masses are seen. Representative sections are submitted.

J1. 4

K. HARDWARE/EXPLANT

Labeled with the patient's name, labeled "hardware/explant", and received in formalin are eight pieces of gray metallic hardware including five fully threaded screws measuring 0.3 to 0.4 cm in length, each 0.2 cm in diameter. Also received are three metallic plates each measuring 1.1 x 0.3 x 0.1 cm. No manufacturer inscription is seen and no soft tissue is identified. Gross only.

Gross dictated by [REDACTED]

INTRAOPERATIVE CONSULTATION: [REDACTED]
OPERATIVE CALL
OPERATIVE CONSULT (FROZEN AND TP):

A. RIGHT TEMPORAL FS AND TP:

- Glioblastoma
[REDACTED]

[page 4 of 4]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.
[REDACTED]

Source: NCI Genomic Data Commons file 90f83b5e-94fd-4f41-9b0a-19eb9c11cf41 (TCGA-28-5219.0BC37B81-620B-4F40-99E5-173F32F091B1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).